Somatic mutation profile of tumor specimen TCGA-DS-A7WF-01A (aliquot TCGA-DS-A7WF-01A-11D-A351-09) from TCGA case TCGA-DS-A7WF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 41.9 years (15,319 days).
Specimen TCGA-DS-A7WF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c71dcac3-6d47-4d2b-aa5b-e51867b24310.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A7WF-10A (Blood Derived Normal), aliquot TCGA-DS-A7WF-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e51c2541-2d8e-4ced-aeb4-0276e58b30dd

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3141T>G p.H1047Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1057519932, COSV55875891, COSV55920782; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60622302; called by muse, mutect2, varscan2
- ADAM19 | c.2537G>A p.C846Y | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772640917, COSV57434056; called by muse, mutect2, varscan2
- ATP2B3 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54853732; called by muse, mutect2, varscan2
- C2orf42 | c.804C>A p.F268L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52451392; called by muse, mutect2, varscan2
- CAMK2B | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs758417712, COSV51659505; called by muse, mutect2, varscan2
- CCDC69 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs114476897; called by muse, mutect2, varscan2
- CD1A | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745915409, COSV56861711; called by muse, mutect2, varscan2
- CHMP7 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as COSV57533279; called by muse, mutect2, varscan2
- CNBD1 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV73074100; called by muse, mutect2, varscan2
- COL5A2 | c.3475C>T p.P1159S | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.468); catalogued as COSV66411560; called by muse, mutect2, varscan2
- DCTN4 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs1243341288; called by muse, mutect2
- DNAJC14 | c.1203G>C p.L401F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100423495, COSV57913603; called by muse, mutect2, varscan2
- ERC2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55639956; called by muse, mutect2, varscan2
- ERICH1 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.164); catalogued as rs552049087, COSV50639274, COSV50639318; called by muse, mutect2, varscan2
- FMN2 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.04); catalogued as rs758344598, COSV60420876; called by muse, mutect2, varscan2
- GDF1 | c.-735C>T | Splice Region (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99897002; called by muse, mutect2, varscan2
- GFRA3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51228666; called by muse, mutect2, varscan2
- GRB7 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV58447393, COSV58449179; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- MYO9A | c.6431C>G p.P2144R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61853907; called by muse, mutect2, varscan2
- NPBWR1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV58695523; called by muse, mutect2, varscan2
- PCYOX1L | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV51003621; called by muse, mutect2, varscan2
- PDE6C | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV65116264; called by muse, mutect2, varscan2
- PI4K2A | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV65701830; called by muse, mutect2, varscan2
- PSD | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as rs945994302, COSV99192424; called by muse, mutect2, varscan2
- RIMS4 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as COSV65720126; called by muse, mutect2, varscan2
- SLC27A1 | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV53098639; called by muse, mutect2
- SLITRK6 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755293525, COSV68390369; called by muse, mutect2, varscan2
- STAC2 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100336283, COSV61066088, COSV61066255; called by muse, mutect2, varscan2
- TNFAIP3 | c.2193G>T p.E731D | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV52800391; called by muse, mutect2, varscan2
- USP10 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV54750684; called by muse, mutect2, varscan2
- USP20 | c.2250C>A p.D750E | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.542); catalogued as COSV59616073; called by muse, mutect2, varscan2
- ZC3H4 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV53414695; called by muse, mutect2, varscan2
- ZNF37A | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs752891741, COSV61074397; called by muse, mutect2, varscan2
- L1CAM | c.3449_3452del p.K1150Tfs*3 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- MED12 | c.6491-18_6491del p.X2164_splice | Splice Site (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- SNAI3 | c.433_452del p.M145Lfs*2 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- AWAT1 | c.129G>A p.P43= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV65738735; called by muse, mutect2, varscan2
- CELF1 | c.108C>T p.F36= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as rs1352080104, COSV60113490, COSV60116284; called by muse, mutect2, varscan2
- GSTT2B | c.168G>A p.T56= | Silent (SNP) | VAF 76/288 reads (26%) | catalogued as rs1569027816, COSV51960265; called by muse, mutect2, varscan2
- HOOK1 | c.214A>C p.R72= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV64619870; called by muse, mutect2, varscan2
- LATS2 | c.2559G>A p.R853= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- MPZL2 | c.492G>A p.L164= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV54049190; called by muse, mutect2, varscan2
- MTUS2 | c.3966G>A p.L1322= (on ENST00000612955 / NM_001366650.1; = p.L301= on NM_015233.6) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV66422097; called by muse, mutect2, varscan2
- PCDHB13 | c.1590C>T p.R530= | Silent (SNP) | VAF 85/198 reads (43%) | catalogued as COSV53398645; called by muse, mutect2, varscan2
- SLC41A1 | c.624C>T p.H208= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65650955; called by muse, mutect2, varscan2
